Surgical pathology report (de-identified scan), TCGA case TCGA-08-0344, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0344-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

08-0344

FINAL PATHOLOGIC DIAGNOSIS

DIAGNOSIS 1:

Glioblastoma multiforme.

See COMMENT.

(Left frontal tumor biopsy, left frontal craniotomy for tumor removal)

DIAGNOSIS 2:

Glioblastoma multiforme.

See COMMENT.

(Left frontal craniotomy for tumor removal)

COMMENT:

NOTES:

COMMENT: Local meningeal infiltration is present.

Nuclear and cytoplasmic pleomorphism, mitotic figures, endothelial proliferation, and necrosis are present; therefore, this tumor is a glioblastoma multiforme by the classification, and a grade 4 astrocytoma by the classification.

Microscopic Description

Diagnosis based on gross and microscopic examinations.

To establish this diagnosis, paraffin embedded sections stained with hematoxylin-eosin required supplementation with GFAP.

Gross Description

[page 2 of 2]
The specimens are received two parts.

Part one, received fresh from the OR, identified as "left frontal tumor biopsy", consists of a fragment of soft, white-pink-red tissue, measuring 1.2 x 1.0 x 0.6 cm. Half of the specimen is submitted for frozen section diagnosis.

FROZEN SECTION DIAGNOSIS

1. Glioblastoma multiforme with necrosis (left frontal tumor biopsy).

The remaining portion of the specimen that was submitted for frozen section diagnosis is entirely submitted in cassette A. The remaining portion of the specimen that was not submitted for frozen section diagnosis is entirely submitted in cassette B.

Part two, received in formalin, labeled with the patient's name and hospital number, consists of multiple fragments of tan tissue measuring 2.0 x 1.4 x 0.4 cm in aggregate. These fragments of tissue are entirely submitted in cassette C. There are also multiple fragments of red-brown friable tissue measuring 2.5 x 3.0 x 1.0 cm in aggregate. Representative sections of these tissues are submitted in cassettes D and E.

Clinical History

with left frontal glioblastoma.

Audit Trail

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically Signed Out By Conversion

Source: NCI Genomic Data Commons file 81e70ec4-1d5c-4728-aca3-93b4675012df (TCGA-08-0344.3195059C-84F1-4EA9-ACAE-9A631732DE86.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).